Somatic mutation profile of tumor specimen 0DNWKW from CCDI case PBCCBE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.9 years (2,141 days).
Specimen 0DNWKW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 11149b89-22f0-4750-8d5f-f1c3d7d214aa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNWJK (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/029d54a6-e77c-4fa6-8a42-87c1f5cebc08

The open-access MAF lists 20 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 3, Nonsense Mutation 2, Splice Region 2, Intron 2, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>A p.S37Y | Missense Mutation (SNP) | VAF 170/384 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- DDX3X | c.870C>A p.Y290* (on ENST00000399959; = p.Y291* on NM_001356.5) | Nonsense Mutation (SNP) | VAF 171/184 reads (93%) | catalogued as rs869320681, CM158031; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.3837T>A p.Y1279* | Nonsense Mutation (SNP) | VAF 158/372 reads (42%) | catalogued as COSV100251386; called by muse, mutect2, varscan2
- CPAMD8 | c.699C>T p.C233= (on ENST00000651564; = p.C186= on NM_015692.5) | Splice Region (SNP) | VAF 108/242 reads (45%) | catalogued as rs753296574, COSV52230882; called by muse, mutect2, varscan2
- DYNC1I1 | c.1753C>T p.R585C | Missense Mutation (SNP) | VAF 90/405 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as rs1463517537, COSV100269623; called by muse, mutect2, varscan2
- H3-2 | c.25C>T p.R9C | Missense Mutation (SNP) | VAF 120/367 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.019); catalogued as rs781927184, COSV67396680; called by muse, mutect2, varscan2
- MUC3A | c.572C>T p.S191F | Missense Mutation (SNP) | VAF 154/304 reads (51%) | SIFT deleterious, low confidence (0); catalogued as rs775778158; called by muse, mutect2
- PPP1CA | c.524-8C>A | Splice Region (SNP) | VAF 34/129 reads (26%) | catalogued as rs764196989, COSV56703071; called by muse, mutect2, varscan2
- TUBD1 | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 256/504 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs572341288; called by muse, mutect2, varscan2
- NIF3L1 | c.848G>A p.G283E (on ENST00000409020 / NM_001369444.1; = p.G256E on NM_021824.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 159/392 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NPAS3 | c.2153C>T p.P718L (on ENST00000356141 / NM_001164749.2; = p.P686L on NM_022123.3) | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- P4HA1 | c.828dup p.G277Rfs*38 | Frame Shift Ins (INS) | VAF 128/534 reads (24%) | called by mutect2, pindel, varscan2
- SAG | c.218A>T p.Q73L | Missense Mutation (SNP) | VAF 16/383 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); called by muse, mutect2
- SLC16A12 | c.1453T>G p.W485G | Missense Mutation (SNP) | VAF 156/389 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- PRKX | c.858A>G p.R286= | Silent (SNP) | VAF 51/123 reads (41%) | called by muse, mutect2, varscan2
- TRMT13 | c.471C>T p.G157= | Silent (SNP) | VAF 106/501 reads (21%) | catalogued as rs373612434; called by muse, mutect2, varscan2
- ZNF324 | c.102C>T p.F34= | Silent (SNP) | VAF 94/231 reads (41%) | catalogued as rs147573504; called by muse, mutect2, varscan2
- AGAP2 | c.2617+17C>T | Intron (SNP) | VAF 127/277 reads (46%) | catalogued as rs370700743; called by muse, mutect2, varscan2
- GLIS3 | c.-69G>C | 5'UTR (SNP) | VAF 50/195 reads (26%) | called by muse, mutect2, varscan2
- KCTD15 | c.693+182G>A | Intron (SNP) | VAF 74/157 reads (47%) | catalogued as rs565367231, COSV52291991; called by muse, mutect2, varscan2
